Gene-level copy-number profile of tumor specimen TCGA-BQ-5878-01A from TCGA case TCGA-BQ-5878, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.4 years (29,010 days).
Specimen TCGA-BQ-5878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.3ad8de16-5e2d-4792-ab6e-6c2c6c21d07f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BQ-5878-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07c6f0d5-3bb4-408a-8455-8d44d98eba1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 1,462; copy number 2: 57,950; copy number 3: 7; copy number 4: 86; copy number 5: 85; copy number 6: 116; copy number 7: 68; copy number 8: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BQ-5878-01A-11D-1588-01): tumor purity 0.94, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:228,352,120–229,271,287, 8 genes (within-gene range 0–1): SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10, PID1, RPL17P14, RN7SKP283.
- chr2:232,479,827–232,682,780, 10 genes (within-gene range 0–1): ECEL1, PRSS56, CHRND, CHRNG, TIGD1, MIR5001, EIF4E2, AC073254.1, EFHD1, RN7SL359P.
- chr2:238,412,642–238,457,520, 4 genes: RNU6-234P, ASB1, AC016999.1, AC016999.2.
- chr2:239,048,168–239,824,764, 15 genes: HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC023787.2, AC023787.3, AC023787.1, AC079612.1, AC079612.2, AC093802.2, AC093802.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:162,371,407–162,838,767, 1 gene, copy number 5 (within-gene range 2–5): KCNH7.
- chr2:162,768,936–163,153,307, 2 genes, copy number 5: KCNH7-AS1, RPL7P61.
- chr2:164,213,539–164,214,414, 1 gene, copy number 5: PRPS1P1.
- chr2:172,084,740–173,052,893, 18 genes, copy number 5 (within-gene range 2–5): DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2.
- chr2:173,297,629–181,105,968, 159 genes, copy number 5–8 (broad region; genes not listed).
- chr2:181,887,851–185,957,063, 41 genes, copy number 5–7: AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32.
- chr2:187,003,220–187,556,288, 1 gene, copy number 7 (within-gene range 4–7): AC007319.1.
- chr2:187,270,698–191,032,314, 55 genes, copy number 5–7 (within-gene range 2–7): RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2.

Autosomal genes at a single copy (total copy number 1): 1,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
